Somatic mutation profile of tumor specimen 0DSG2H from CCDI case PBCICY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,315 days).
Specimen 0DSG2H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ed22255-dfa2-4aff-9267-dc861d795b6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSG2O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13e190c0-4de9-465d-855b-db3dc467e6b2

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPT2 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 305/559 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs773644967, COSV100291119; called by muse, mutect2, varscan2
- CCDC146 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 117/570 reads (21%) | catalogued as rs371350411; called by muse, mutect2, varscan2
- MAP6 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 323/607 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as rs573813818, COSV59077004; called by muse, mutect2, varscan2
- AHNAK | c.721C>G p.H241D | Missense Mutation (SNP) | VAF 276/447 reads (62%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LY6G6E | c.178+35G>A | Intron (SNP) | VAF 16/500 reads (3%) | called by muse, mutect2
